Somatic mutation profile of tumor specimen TCGA-AA-3811-01A (aliquot TCGA-AA-3811-01A-01D-1981-10) from TCGA case TCGA-AA-3811, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with neuroendocrine differentiation; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 84.6 years (30,893 days).
Specimen TCGA-AA-3811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1b52fca-95b4-404f-932a-e36c3772d627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3811-10A (Blood Derived Normal), aliquot TCGA-AA-3811-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d300d561-9fc9-46da-bf33-c8987df2e2f0

The open-access MAF lists 1,742 somatic variants for this specimen: 1,309 protein-altering or splice-affecting, 393 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 972, Silent 393, Frame Shift Del 197, Nonsense Mutation 49, Frame Shift Ins 35, Splice Site 28, Intron 20, In Frame Del 16, Splice Region 10, RNA 8, 3'UTR 5, 3'Flank 3.

Variants (750 of 1,742; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 40/176 reads (23%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- COL7A1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as rs121912854, CM940313; ClinVar: pathogenic; called by muse, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 102/136 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 548/694 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- EGFR | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 530/644 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477025000, COSV51779162, COSV51807036; called by muse, mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 150/421 reads (36%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel
- LAMA2 | c.3829C>T p.R1277* | Nonsense Mutation (SNP) | VAF 26/36 reads (72%) | catalogued as rs1554269891, COSV70354446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMAA | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs1029096863, CM113629, COSV99849569; ClinVar: pathogenic; called by muse, mutect2
- NEK8 | c.2076dup p.*693Lfs*86 | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | catalogued as rs755820155; ClinVar: pathogenic; called by mutect2, varscan2
- PGR | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | hotspot (GDC flag); catalogued as rs776604342, COSV99677260; called by muse, mutect2, varscan2
- SLC12A6 | c.550del p.Q184Kfs*19 (on ENST00000354181 / NM_001365088.1; = p.Q133Kfs*19 on NM_005135.2) | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs1057517109; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 119/147 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAR | c.125dup p.T44Hfs*3 | Frame Shift Ins (INS) | VAF 32/70 reads (46%) | catalogued as rs750549499; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 39/71 reads (55%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100228408; called by mutect2, varscan2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by mutect2, varscan2
- ABCA1 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV101036379; called by muse, varscan2
- ABCB9 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs775396358, COSV99757500; called by muse, mutect2, varscan2
- ABCC2 | c.2624A>G p.H875R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1258429983, COSV100966352; called by muse, mutect2, varscan2
- ABCC6 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs190761354, COSV52743034; called by muse, mutect2, varscan2
- ABCD1 | c.1804A>G p.K602E | Missense Mutation (SNP) | VAF 314/460 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as CM110913, COSV99497154; called by muse, varscan2
- ABHD18 | c.623C>T p.A208V (on ENST00000398965 / NM_001039717.2; = p.A81V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761660121, COSV66294178; called by muse, mutect2, varscan2
- ABR | c.2077G>A p.A693T (on ENST00000302538 / NM_021962.5; = p.A656T on NM_001092.5) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99347329; called by muse, mutect2, varscan2
- AC011455.2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746697410, COSV99671053; called by muse, mutect2, varscan2
- AC090517.4 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772319117, COSV99973933; called by muse, varscan2
- ACACB | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768707560, COSV100622172; called by mutect2, varscan2
- ACADS | c.933+2T>C p.X311_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99656590; called by muse, mutect2, varscan2
- ACBD3 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 223/317 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs763517769, COSV100830871; called by muse, mutect2, varscan2
- ACOT2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV99468718; called by muse, mutect2
- ACP4 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV54519357; called by muse, mutect2
- ACP7 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747641850, COSV100488395; called by muse, mutect2, varscan2
- ACSBG2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99397117; called by muse, varscan2
- ACSM1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV99532402; called by muse, mutect2, varscan2
- ACSM2A | c.1415G>A p.R472Q (on ENST00000219054; = p.R393Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs556547446, COSV54590739; called by muse, mutect2, varscan2
- ACTL9 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs373541326; called by muse, mutect2
- ADAM33 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773020678, COSV62935537; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS12 | c.3718G>A p.V1240I | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100710121; called by muse, mutect2, varscan2
- ADAMTS16 | c.2150G>A p.C717Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274205723, COSV99939649; called by muse, mutect2, varscan2
- ADAMTS4 | c.2057G>A p.S686N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV63490251; called by muse, mutect2
- ADAR | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs750065985, COSV52715948; called by mutect2, varscan2
- ADCY10 | c.4790del p.N1597Tfs*4 | Frame Shift Del (DEL) | VAF 36/390 reads (9%) | catalogued as rs753500756; called by pindel, varscan2
- ADCY8 | c.2777A>G p.D926G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99650296; called by muse, mutect2, varscan2
- ADD2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372010773; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE5 | c.1873G>A p.A625T (on ENST00000242786 / NM_078481.4; = p.A532T on NM_001784.5) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99660086; called by muse, mutect2
- ADGRF4 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536284658, COSV51956797; called by muse, mutect2, varscan2
- ADGRG4 | c.5615C>G p.S1872C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV54955683, COSV99794114; called by mutect2, varscan2
- ADGRG4 | c.8396G>C p.W2799S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99794117; called by muse, mutect2
- ADGRL4 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as COSV100875502; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 64/232 reads (28%) | catalogued as rs761350619; called by mutect2, varscan2
- ADORA1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1218495662, COSV58813581; called by muse, mutect2
- AFDN | c.1770A>G p.R590= | Splice Region (SNP) | VAF 18/321 reads (6%) | catalogued as COSV100652315; called by muse, mutect2
- AFDN | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60044122; called by muse, mutect2, varscan2
- AHNAK2 | c.16394T>C p.V5465A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV60920373; called by muse, mutect2
- AKAP11 | c.519T>A p.D173E | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as COSV99213383; called by muse, mutect2
- AKAP8 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99511653; called by muse, mutect2
- ALDH4A1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs142969512, COSV51893094; called by muse, mutect2
- ALK | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV101200890; called by muse, mutect2
- ALMS1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376632767, COSV52504065; called by muse, mutect2, varscan2
- AMBN | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100534233; called by muse, mutect2, varscan2
- AMFR | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.655); catalogued as rs764962608, COSV51922655; called by mutect2, varscan2
- AMPH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768583906, COSV57761502; called by muse, mutect2, varscan2
- ANGPT4 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1205293026, COSV101124607; called by muse, mutect2, varscan2
- ANGPTL2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752232897, COSV99400564; called by muse, mutect2, varscan2
- ANGPTL5 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100527587; called by muse, mutect2
- ANK3 | c.9910C>T p.P3304S | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99777780; called by muse, mutect2, varscan2
- ANKMY2 | c.272-2A>G p.X91_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as COSV100186807; called by muse, mutect2, varscan2
- ANKRD29 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99408973; called by muse, mutect2, varscan2
- ANO2 | c.1004G>A p.R335H (on ENST00000356134 / NM_001278597.3; = p.R339H on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs1486183196, COSV59028580; called by muse, mutect2
- ANO8 | c.2875G>A p.G959R | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs776981751, COSV99343954; called by muse, mutect2, varscan2
- ANXA6 | c.1518G>T p.T506= | Splice Region (SNP) | VAF 8/82 reads (10%) | catalogued as COSV62907323; called by mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs753324780, COSV52227333; called by pindel, varscan2
- AP4M1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373162905; called by mutect2, varscan2
- APBB2 | c.1928A>G p.K643R (on ENST00000295974 / NM_001166050.2; = p.K644R on NM_004307.2) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99922293; called by muse, mutect2, varscan2
- APBB2 | c.1016C>T p.T339M (on ENST00000295974 / NM_001166050.2; = p.T340M on NM_004307.2) | Missense Mutation (SNP) | VAF 128/402 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs374925325; called by muse, mutect2, varscan2
- APC | c.4595A>G p.D1532G | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs904971132, COSV99964547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLF | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 39/114 reads (34%) | catalogued as rs773250190, COSV58148815; called by muse, mutect2, varscan2
- APLNR | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200854787, COSV57242011; called by muse, mutect2
- APOL5 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99968317; called by muse, mutect2
- APP | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61000615; called by muse, mutect2, varscan2
- ARFGAP3 | c.1267A>G p.N423D | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV99605057; called by muse, mutect2, varscan2
- ARHGAP15 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs760147596, COSV54483751; called by muse, varscan2
- ARHGAP27 | c.1182del p.G395Afs*24 (on ENST00000428638 / NM_001282290.1; = p.G54Afs*24 on NM_199282.3) | Frame Shift Del (DEL) | VAF 81/145 reads (56%) | catalogued as rs1567704517; called by mutect2, pindel, varscan2
- ARHGAP33 | c.2707T>C p.S903P | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.09); catalogued as COSV99137424; called by muse, mutect2, varscan2
- ARHGAP36 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99035104; called by muse, varscan2
- ARHGEF1 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100528812; called by muse, mutect2, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2, varscan2
- ARHGEF26 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.385); catalogued as rs760809133, COSV62843908; called by mutect2, varscan2
- ARHGEF7 | c.895C>T p.R299W (on ENST00000375741 / NM_001113511.2; = p.R121W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs746611764, COSV99520763; called by muse, mutect2, varscan2
- ARHGEF7 | c.2273G>A p.R758H (on ENST00000375741 / NM_001113511.2; = p.R737H on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.726); catalogued as rs1165161750, COSV99520770; called by muse, mutect2
- ARID4A | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530045241, COSV100793936; called by muse, mutect2, varscan2
- ARRB1 | c.466_468del p.E156del | In Frame Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs759500119; called by pindel, varscan2
- ASH1L | c.7751A>G p.D2584G (on ENST00000368346 / NM_001366177.2; = p.D2579G on NM_018489.3) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100853052; called by muse, mutect2, varscan2
- ASPDH | c.224C>T p.A75V (on ENST00000389208 / NM_001114598.2; = p.A20V on NM_001024656.3) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100975802; called by muse, mutect2
- ASPM | c.6074T>C p.V2025A | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99659301; called by muse, mutect2, varscan2
- ASTN2 | c.1652G>A p.R551H (on ENST00000313400 / NM_001365069.1; = p.R500H on NM_014010.5) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs571117828, COSV57788982; called by muse, mutect2, varscan2
- ASZ1 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99497675; called by mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs768611141; called by mutect2, varscan2
- ATF7IP | c.1646-2A>G p.X549_splice | Splice Site (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99661068; called by muse, mutect2, varscan2
- ATP10D | c.2278G>T p.G760* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99904988; called by muse, mutect2, varscan2
- ATP13A3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as rs746412654, COSV55466509; called by mutect2, varscan2
- ATP1A1 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99814075; called by muse, mutect2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV53805755, COSV53811872; called by muse, varscan2
- ATP2B1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 60/121 reads (50%) | catalogued as COSV99665093; called by muse, mutect2, varscan2
- ATP6V1A | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769264993, COSV56361556; called by muse, mutect2, varscan2
- ATP9A | c.1688T>A p.I563N | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100124192; called by muse, mutect2
- ATR | c.5246T>C p.L1749P | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV100637575; called by muse, mutect2, varscan2
- ATRN | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99496414; called by muse, mutect2
- AVPI1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs770933514, COSV65697422; called by muse, mutect2, varscan2
- B3GNT7 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as rs746899567, COSV55006857; called by muse, mutect2, varscan2
- BCAN | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs759486942, COSV61257438; called by mutect2, varscan2
- BCHE | c.1409T>G p.I470S | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100011933; called by muse, mutect2
- BCL2L13 | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV58226512; called by muse, mutect2, varscan2
- BCR | c.2258G>A p.C753Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV100005839; called by muse, mutect2, varscan2
- BEND5 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100884077; called by muse, mutect2
- BEND6 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1047434405, COSV100876728; called by muse, mutect2, varscan2
- BHMT | c.594del p.G199Afs*8 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs773277176; called by mutect2, pindel, varscan2
- BICD1 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 83/528 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs148101509, COSV99861883; called by muse, mutect2, varscan2
- BIRC6 | c.4843G>A p.V1615I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs565438694, COSV101427742; called by muse, mutect2, varscan2
- BIRC6 | c.13148T>C p.L4383P | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101427743; called by muse, mutect2, varscan2
- BMP10 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1420667461, COSV99770246; called by muse, mutect2
- BMPER | c.1745+2T>C p.X582_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99778636; called by muse, mutect2
- BNC2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV101031800; called by muse, mutect2, varscan2
- BNIP1 | c.410C>G p.T137S | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs969394774, COSV99199357; called by muse, mutect2
- BNIP2 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99985570; called by muse, mutect2
- BOD1L1 | c.4223A>G p.D1408G | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99238154; called by muse, mutect2, varscan2
- BOD1L1 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99238157; called by muse, mutect2
- BRIP1 | c.2243A>G p.Y748C | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99368969; called by muse, mutect2
- BRPF1 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs748786588, COSV100121062; called by muse, mutect2, varscan2
- BRSK1 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100510211; called by muse, mutect2, varscan2
- C11orf52 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99585506; called by muse, mutect2
- C1QC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.145); catalogued as rs772221556, COSV65889392; called by muse, mutect2, varscan2
- C1QTNF1 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100189681; called by muse, mutect2, varscan2
- C1QTNF1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189683; called by muse, mutect2, varscan2
- C1S | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV100196307; called by muse, varscan2
- C8B | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100980674; called by muse, mutect2, varscan2
- C9orf72 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101186473; called by muse, mutect2, varscan2
- CA6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs533616544, COSV66262258, COSV66263535; called by muse, mutect2, varscan2
- CACNA1C | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV100214413; called by muse, mutect2, varscan2
- CACNB2 | c.1823G>A p.R608H (on ENST00000324631 / NM_201596.3; = p.R553H on NM_000724.4) | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs771011929, COSV56644129; called by muse, mutect2, varscan2
- CACTIN | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50267415; called by muse, mutect2, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by mutect2, varscan2
- CADPS | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99335419; called by muse, mutect2, varscan2
- CARD11 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62717031; called by muse, mutect2
- CARD6 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99620042; called by muse, mutect2, varscan2
- CASP1 | c.1158G>A p.M386I (on ENST00000436863 / NM_033292.4; = p.M365I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99507049; called by muse, varscan2
- CASQ2 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99796922; called by muse, varscan2
- CASS4 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100824499; called by muse, mutect2
- CATSPER4 | c.685del p.S229Pfs*5 | Frame Shift Del (DEL) | VAF 42/317 reads (13%) | catalogued as rs1557631503; called by mutect2, varscan2
- CATSPERB | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV99830717; called by muse, mutect2, varscan2
- CBX1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99847954; called by muse, mutect2, varscan2
- CBX8 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99485709; called by muse, mutect2, varscan2
- CBY1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs762674357, COSV99319835; called by mutect2, varscan2
- CCAR1 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99770487; called by mutect2, varscan2
- CCDC103 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV53651621; called by muse, mutect2, varscan2
- CCDC186 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100991083, COSV65160616; called by muse, mutect2, varscan2
- CCDC28B | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 113/172 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99356254; called by muse, mutect2, varscan2
- CCDC40 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs779895005, COSV66476198; called by muse, mutect2, varscan2
- CCDC88C | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs757076773, COSV101104686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC93 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV100098238; called by muse, mutect2
- CCNA1 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as COSV99714196; called by muse, mutect2, varscan2
- CCNG1 | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100243495; called by muse, mutect2, varscan2
- CCSER2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56505073, COSV99825345; called by mutect2, varscan2
- CCT6B | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100030388; called by muse, mutect2, varscan2
- CD177 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945765; called by muse, mutect2
- CD1B | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV63804572; called by muse, mutect2
- CD37 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs892651074, COSV100114813; called by muse, mutect2, varscan2
- CD84 | c.908A>C p.K303T (on ENST00000311224 / NM_001184879.2; = p.K286T on NM_003874.4) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs200118969, COSV100245769; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 20/155 reads (13%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC23 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101203055; called by muse, mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 21/171 reads (12%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2, varscan2
- CDH11 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV99216880; called by muse, mutect2, varscan2
- CDH4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs751765138, COSV64646935; called by muse, mutect2, varscan2
- CDHR4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1030618164, COSV100323466; called by muse, mutect2
- CDON | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.29); catalogued as COSV99700409; called by muse, mutect2
- CDX2 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV101122641; called by muse, mutect2
- CENPU | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs1050685241, COSV99859703; called by muse, mutect2, varscan2
- CEP135 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99954031; called by muse, mutect2, varscan2
- CEP70 | c.1588A>G p.R530G | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV99388729; called by muse, mutect2
- CES3 | c.1186C>A p.L396I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV100309767; called by muse, mutect2, varscan2
- CFH | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs371192606, CM104000; called by muse, mutect2, varscan2
- CH25H | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1380052356, COSV100897325, COSV100897402; called by muse, mutect2
- CHD4 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV58904577; called by muse, mutect2
- CHD6 | c.5253G>T p.E1751D | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV100950479; called by muse, mutect2, varscan2
- CHD6 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV58553993; called by muse, mutect2
- CHRNA3 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569381256, COSV58774647; called by muse, mutect2, varscan2
- CHRNA7 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 70/720 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1261854197, COSV100180652; called by muse, mutect2, varscan2
- CIART | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51744866; called by muse, mutect2
- CIT | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99948100; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs752250702; called by mutect2, varscan2
- CLINT1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567702393, COSV51626206; called by muse, mutect2, varscan2
- CLNS1A | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); catalogued as COSV99627859; called by muse, mutect2
- CLSTN1 | c.1270G>A p.G424R (on ENST00000377298 / NM_001009566.3; = p.G414R on NM_014944.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs369660230; called by muse, mutect2, varscan2
- CNGA1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs759487836, COSV62053254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGA3 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99735915; called by mutect2, varscan2
- CNKSR1 | c.1456A>G p.T486A (on ENST00000374253 / NM_001297647.2; = p.T479A on NM_006314.3) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV100128163; called by muse, mutect2, varscan2
- CNTN4 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV101281109; called by muse, mutect2, varscan2
- COG6 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.761); catalogued as COSV62998072; called by muse, mutect2, varscan2
- COL11A2 | c.3925G>A p.G1309R (on ENST00000341947 / NM_080680.3; = p.G1202R on NM_080679.2) | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779569420, COSV59495931; called by muse, mutect2, varscan2
- COL12A1 | c.9071G>C p.G3024A | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59401173; called by muse, mutect2
- COL14A1 | c.3978A>C p.K1326N | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99917627; called by muse, mutect2
- COL1A1 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV56806881; called by muse, mutect2, varscan2
- COL4A5 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100086210; called by muse, mutect2, varscan2
- COL4A5 | c.4655T>C p.L1552P | Missense Mutation (SNP) | VAF 214/321 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100086213; called by muse, mutect2, varscan2
- COL4A5 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372369187, COSV60363379; called by muse, mutect2, varscan2
- COPS9 | c.115G>A p.V39I (on ENST00000607357 / NM_001163424.2; = p.V70I on NM_138336.1) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1369380202, COSV56228451, COSV56229009, COSV56229090; called by muse, mutect2
- COX11 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1037345679, COSV100173964; called by muse, mutect2, varscan2
- CPNE3 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52207701; called by muse, mutect2
- CPNE4 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV70190261; called by muse, mutect2
- CPS1 | c.2020A>G p.N674D | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.524); catalogued as COSV99241705; called by mutect2, varscan2
- CPSF3 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99432376; called by muse, varscan2
- CREBBP | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV99268247; called by muse, mutect2, varscan2
- CRELD2 | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470164794, COSV100077775; called by muse, mutect2, varscan2
- CRTAM | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99911693; called by muse, mutect2
- CRYBG1 | c.3952dup p.S1318Kfs*38 | Frame Shift Ins (INS) | VAF 26/152 reads (17%) | catalogued as rs1271696161; called by mutect2, pindel, varscan2
- CSDE1 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99793876; called by muse, mutect2, varscan2
- CSMD3 | c.7676G>A p.G2559D (on ENST00000297405 / NM_001363185.1; = p.G2455D on NM_052900.3) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158781, COSV99821688; called by muse, mutect2
- CSNK2A2 | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99345119; called by muse, mutect2
- CSRNP1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759995863, COSV99826653; called by muse, varscan2
- CSTF3 | c.1795+1G>A p.X599_splice | Splice Site (SNP) | VAF 25/394 reads (6%) | catalogued as rs1406366178, COSV60614751; called by muse, mutect2
- CTDSPL | c.415A>G p.T139A (on ENST00000273179 / NM_001008392.2; = p.T128A on NM_005808.3) | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV99828472; called by muse, mutect2, varscan2
- CTNNA2 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV100559678, COSV58136648, COSV58140250; called by muse, mutect2, varscan2
- CTNNB1 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV100845948, COSV62691124; called by muse, varscan2
- CTNNB1 | c.482A>T p.N161I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100845949; called by muse, mutect2
- CTSC | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as COSV99910427; called by muse, varscan2
- CTSL | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419953841, COSV58246620; called by muse, mutect2
- CUL5 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV101263613; called by muse, mutect2, varscan2
- CUL7 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV99537646; called by muse, mutect2
- CUX2 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.978); catalogued as COSV99918352; called by muse, mutect2, varscan2
- CUZD1 | c.1302T>A p.N434K | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs370233601; called by muse, mutect2, varscan2
- CXCR1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1008352928, COSV55282387; called by muse, mutect2
- CXorf66 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 306/464 reads (66%) | SIFT tolerated (0.39); PolyPhen benign (0.201); catalogued as COSV100983810; called by muse, mutect2, varscan2
- CYB561 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as rs559436381, COSV62539471; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | catalogued as rs775988957; called by mutect2, varscan2
- CYP1A1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs201174966, COSV65697096; called by muse, mutect2, varscan2
- CYP21A2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.218); catalogued as rs747079101, CM033605, COSV64475261; called by muse, mutect2
- D2HGDH | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs539220817, COSV58319949; called by muse, varscan2
- DAXX | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs375012684; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 66/129 reads (51%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBNDD2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100619490; called by muse, varscan2
- DCTN4 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69783127; called by muse, mutect2, varscan2
- DCTPP1 | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100073478; called by muse, mutect2, varscan2
- DDR2 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV100906126; called by muse, mutect2
- DDX1 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99245712; called by muse, mutect2, varscan2
- DDX24 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.356); catalogued as COSV100427791; called by muse, mutect2, varscan2
- DDX31 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs370315245; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 21/105 reads (20%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DEUP1 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1406842387, COSV99976536; called by mutect2, varscan2
- DGKD | c.2197C>T p.P733S (on ENST00000264057 / NM_152879.3; = p.P689S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99895056; called by mutect2, varscan2
- DGKZ | c.2900C>T p.T967M (on ENST00000454345 / NM_001105540.2; = p.T779M on NM_003646.4) | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs368913796; called by muse, mutect2, varscan2
- DHDH | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs368374944; called by muse, mutect2, varscan2
- DHX58 | c.1156T>C p.W386R | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99287948; called by muse, mutect2, varscan2
- DIPK2B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs775096087, COSV65005627; called by muse, mutect2, varscan2
- DLG2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99712025; called by muse, mutect2, varscan2
- DLL1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV64537900; called by muse, mutect2
- DNAH1 | c.4171T>C p.S1391P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101324385; called by muse, mutect2, varscan2
- DNAH10 | c.1487del p.K496Rfs*10 (on ENST00000409039; = p.K435Rfs*10 on NM_207437.3) | Frame Shift Del (DEL) | VAF 15/151 reads (10%) | catalogued as COSV68987525, COSV68996854; called by pindel, varscan2
- DNAH10 | c.8570G>A p.R2857H (on ENST00000409039; = p.R2796H on NM_207437.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs763152052, COSV68994327; called by muse, mutect2
- DNAH9 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52368777; called by muse, mutect2
- DNAH9 | c.6526G>A p.V2176I | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs756835987, COSV99303286; called by muse, mutect2, varscan2
- DNAH9 | c.10601G>A p.R3534Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs199850205, COSV99305729; called by mutect2, varscan2
- DNAJC16 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101012492; called by muse, mutect2
- DNAJC21 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100331478; called by muse, varscan2
- DNAJC24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV71938535; called by muse, mutect2
- DNMT3B | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV52418076, COSV99140403; called by muse, mutect2
- DNPEP | c.1172A>T p.Y391F | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56110377, COSV56111279; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 81/155 reads (52%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs747068226, COSV99373105; called by muse, mutect2, varscan2
- DPY19L2 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201845477, COSV61045326; called by muse, varscan2
- DPY19L4 | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 21/449 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV101363037; called by muse, mutect2
- DRC3 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV100572587; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2, varscan2
- DSG4 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100355138; called by muse, mutect2
- DST | c.18078G>A p.M6026I (on ENST00000361203 / NM_001374722.1; = p.M3723I on NM_015548.5) | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV99749896; called by muse, mutect2
- DTL | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100877127; called by muse, mutect2, varscan2
- DTX1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs370481380; called by mutect2, varscan2
- DYNC1H1 | c.5774G>A p.R1925Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1183114043; called by muse, mutect2, varscan2
- DYNC1H1 | c.10289C>T p.A3430V | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV100794233; called by muse, mutect2, varscan2
- DYRK4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs766865898, COSV50539305; called by muse, mutect2, varscan2
- DYSF | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV99243600; called by muse, mutect2
- DYSF | c.3461T>C p.L1154P | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99243605; called by muse, mutect2
- ECE1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 77/123 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs150644074; called by muse, mutect2, varscan2
- ECM2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs775294587, COSV100755896, COSV60741649; called by muse, mutect2, varscan2
- ECT2L | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV62882814; called by muse, mutect2, varscan2
- EDNRA | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100163138; called by mutect2, varscan2
- EEF1AKNMT | c.1882G>A p.A628T (on ENST00000361735 / NM_015935.5; = p.A542T on NM_014955.3) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1454780232, COSV100675737; called by muse, mutect2
- EEF2 | c.299T>G p.I100S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500529; called by muse, mutect2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 41/142 reads (29%) | catalogued as rs760712775, COSV51135066; called by mutect2, pindel, varscan2
- EGFLAM | c.2624G>A p.G875D (on ENST00000354891 / NM_001205301.2; = p.G867D on NM_152403.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379616; called by muse, mutect2, varscan2
- EGR2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99653917; called by muse, mutect2, varscan2
- EHD1 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1487135938, COSV100276784, COSV57737337; called by muse, mutect2, varscan2
- EIF3B | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs181409131, COSV100703502; called by muse, mutect2, varscan2
- EIF3L | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs376536658; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2471A>G p.H824R | Missense Mutation (SNP) | VAF 148/272 reads (54%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); catalogued as rs1273489678, COSV100348791; called by muse, mutect2, varscan2
- EIF4G2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 238/661 reads (36%) | catalogued as COSV100379325; called by muse, mutect2, varscan2
- ELAVL2 | c.381A>T p.L127F | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805110; called by muse, mutect2, varscan2
- ELMOD2 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs373389261; called by muse, mutect2, varscan2
- ELP3 | c.1101-1G>T p.X367_splice | Splice Site (SNP) | VAF 36/399 reads (9%) | catalogued as COSV99833739; called by muse, mutect2
- ENPP2 | c.1991G>A p.S664N (on ENST00000075322 / NM_001040092.3; = p.S716N on NM_006209.5) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99307261; called by muse, mutect2, varscan2
- EOMES | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99841623; called by muse, mutect2, varscan2
- EP400 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248383112, COSV57773721; called by muse, mutect2, varscan2
- EPG5 | c.2945A>G p.Y982C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV99956314; called by muse, mutect2
- EPHA3 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs761576191, COSV60713368; called by muse, mutect2, varscan2
- EPHA4 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV56037259; called by muse, mutect2, varscan2
- EPHA5 | c.1060T>C p.C354R | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99895348; called by muse, mutect2, varscan2
- EPHA6 | c.3322C>T p.R1108* | Nonsense Mutation (SNP) | VAF 50/79 reads (63%) | catalogued as rs1394452957, COSV101060616; called by muse, mutect2, varscan2
- EPRS1 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100859270; called by muse, mutect2, varscan2
- EPS15L1 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV50170567; called by muse, mutect2
- ERG | c.1123G>A p.A375T (on ENST00000398919 / NM_001243428.1; = p.A351T on NM_004449.4) | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733296, COSV99901229; called by muse, mutect2
- ERI2 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184021; called by muse, mutect2, varscan2
- ESCO2 | c.1058T>C p.M353T | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1405136328, COSV100533064; called by muse, mutect2, varscan2
- ESR1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs140555278; called by mutect2, varscan2
- ESX1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.246); catalogued as COSV65424786; called by muse, mutect2, varscan2
- EXTL3 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55038180; called by mutect2, varscan2
- F7 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as CM090299, COSV100660927; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM135B | c.3346T>G p.L1116V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.918); catalogued as COSV52708161; called by muse, mutect2
- FAM151A | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs201727345; called by muse, mutect2, varscan2
- FAM170A | c.311T>C p.L104S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs377460947; called by mutect2, varscan2
- FAM181A | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765516099, COSV50889593; called by muse, mutect2, varscan2
- FAM200A | c.889T>C p.F297L | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV101282695; called by muse, mutect2, varscan2
- FAM24A | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV100925064; called by muse, mutect2
- FAM47A | c.2255G>A p.G752D | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.481); catalogued as COSV100649668; called by muse, mutect2
- FAM47B | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777326686, COSV100263958, COSV61452955; called by muse, varscan2
- FAM83B | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100173920; called by muse, mutect2
- FAN1 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs372355885; called by muse, mutect2, varscan2
- FAT1 | c.7866T>A p.D2622E | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101498633; called by muse, varscan2
- FAT1 | c.7770T>G p.N2590K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101498637; called by muse, varscan2
- FAT2 | c.12694A>T p.M4232L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99941392; called by muse, mutect2, varscan2
- FAT2 | c.8546C>T p.A2849V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99941393; called by muse, mutect2, varscan2
- FAXDC2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100394097; called by mutect2, varscan2
- FBF1 | c.2986C>T p.R996C (on ENST00000586717; = p.R1011C on NM_001319193.1) | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs369895761; called by muse, varscan2
- FBLN2 | c.2342G>A p.C781Y | Missense Mutation (SNP) | VAF 101/171 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99851215; called by muse, mutect2, varscan2
- FBXO38 | c.2921A>C p.D974A (on ENST00000340253 / NM_205836.3; = p.D899A on NM_030793.5) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99693028; called by muse, mutect2, varscan2
- FBXO44 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52356204; called by muse, mutect2, varscan2
- FBXO48 | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100376300; called by muse, mutect2, varscan2
- FCGBP | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1334448702; called by muse, mutect2
- FCHO1 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99405738; called by muse, mutect2, varscan2
- FCSK | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs572464313, COSV55367323; called by muse, varscan2
- FEN1 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1013335904; called by muse, mutect2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | catalogued as rs747094222, COSV67548414; called by mutect2, varscan2
- FGD1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs1160132540, COSV100910748, COSV100910903; called by muse, mutect2, varscan2
- FHOD1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99263745; called by muse, mutect2
- FKBP15 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780183295, COSV52272940; called by muse, mutect2, varscan2
- FKBP9 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99638809; called by muse, mutect2
- FKTN | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as rs201590151, COSV99795235; ClinVar: uncertain significance; called by muse, mutect2
- FLNC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100367524, COSV57965616; called by muse, mutect2, varscan2
- FLRT1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs763041801, COSV99734494; called by muse, mutect2, varscan2
- FMNL2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs377497365; called by muse, mutect2
- FN1 | c.5329G>A p.V1777M | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs369072643; called by muse, mutect2, varscan2
- FNDC3A | c.2038C>T p.Q680* (on ENST00000492622 / NM_001079673.2; = p.Q624* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 75/131 reads (57%) | catalogued as COSV101256570; called by muse, mutect2, varscan2
- FOXH1 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100023414; called by muse, mutect2
- FRAS1 | c.1887del p.K630Rfs*67 | Frame Shift Del (DEL) | VAF 15/135 reads (11%) | catalogued as rs776570778; called by mutect2, pindel, varscan2
- FSTL4 | c.2465C>T p.T822M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs375184077; called by muse, varscan2
- FYCO1 | c.4339A>G p.I1447V | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV99945055; called by muse, mutect2, varscan2
- FZD10 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764506823, COSV57473825; called by muse, mutect2, varscan2
- FZD8 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020170; called by muse, mutect2, varscan2
- GABRA3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 82/112 reads (73%) | catalogued as rs777972856, COSV64794901; called by muse, mutect2, varscan2
- GADD45GIP1 | c.553_555del p.K185del | In Frame Del (DEL) | VAF 43/122 reads (35%) | catalogued as rs777674072; called by pindel, varscan2
- GALNT17 | c.1645T>C p.Y549H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100351831; called by muse, mutect2
- GBP1 | c.1728A>G p.I576M | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV65083885; called by muse, mutect2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | catalogued as rs34148688; called by mutect2, pindel
- GCDH | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs768925619, CM980873, CM980874, COSV99535643; called by muse, mutect2, varscan2
- GCN1 | c.5953A>G p.I1985V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV100324517; called by muse, mutect2, varscan2
- GGA2 | c.1796_1798del p.G599del | In Frame Del (DEL) | VAF 25/74 reads (34%) | catalogued as rs749721440; called by mutect2, pindel, varscan2
- GIGYF1 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV99308636; called by muse, mutect2, varscan2
- GIMAP5 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100500202; called by muse, mutect2
- GJA8 | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs145146702, COSV99569009; called by muse, mutect2, varscan2
- GJB3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs369979083, CM149748; ClinVar: likely benign; called by mutect2, varscan2
- GLP1R | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 55/73 reads (75%) | catalogued as rs141990898; called by muse, mutect2, varscan2
- GLRB | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100029394; called by muse, mutect2
- GNAI1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1211791957, COSV63524154; called by muse, mutect2, varscan2
- GOT1 | c.253T>G p.S85A | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100981628; called by muse, mutect2
- GPATCH8 | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1555619312, COSV100132396; called by muse, mutect2, varscan2
- GPLD1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.089); catalogued as rs774586094, COSV100014879; called by mutect2, varscan2
- GPR182 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs142483692; called by muse, mutect2, varscan2
- GPR3 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs775992272; called by mutect2, varscan2
- GPR63 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.226); catalogued as COSV100013083; called by muse, mutect2, varscan2
- GPR75 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs142326404, COSV100765734; called by muse, mutect2, varscan2
- GPRC5A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs775011273, COSV50007301; called by muse, mutect2, varscan2
- GREB1 | c.927del p.K311Nfs*65 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | catalogued as rs761359837; called by mutect2, pindel, varscan2
- GRID1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199714522; called by muse, mutect2, varscan2
- GRM5 | c.3632C>T p.S1211L (on ENST00000305447 / NM_001143831.2; = p.S1179L on NM_000842.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59612986; called by muse, mutect2, varscan2
- GRM6 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs111526982, COSV99179420; called by muse, mutect2, varscan2
- GSAP | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV99990332; called by muse, mutect2
- GSTA5 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99489350; called by muse, mutect2
- GTF3C2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 10/169 reads (6%) | catalogued as COSV53125771; called by muse, mutect2
- H1-2 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59189752; called by muse, mutect2
- H2BC12 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.067); catalogued as COSV100804551; called by muse, mutect2, varscan2
- H2BC5 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99175191; called by muse, mutect2
- HACD4 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs751798439, COSV72136635, COSV72136856; called by muse, mutect2, varscan2
- HAUS1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV99958697; called by muse, mutect2
- HAUS6 | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100997718; called by muse, mutect2
- HDAC6 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs782183158, COSV100490502; called by muse, mutect2, varscan2
- HEATR1 | c.4735G>A p.A1579T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs747400321, COSV63982982; called by muse, mutect2, varscan2
- HECTD4 | c.6259G>A p.A2087T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408221012, COSV66393718; called by muse, mutect2, varscan2
- HEPN1 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV53430839; called by muse, mutect2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 64/262 reads (24%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HEY1 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100559140; called by muse, mutect2, varscan2
- HHIP | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1179081644, COSV56838272, COSV56845825; called by muse, mutect2, varscan2
- HIC2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs371166847, COSV68041684; called by muse, varscan2
- HIVEP3 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99911188; called by muse, mutect2
- HJURP | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs562372914, COSV100982540; called by mutect2, varscan2
- HK1 | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV100065122; called by muse, mutect2, varscan2
- HNRNPL | c.374T>C p.F125S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99669879; called by muse, mutect2, varscan2
- HOOK1 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100968950; called by muse, mutect2, varscan2
- HOXA7 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636170; called by muse, mutect2
- HPSE2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs767720704, COSV65188152, COSV65188189; called by muse, mutect2, varscan2
- HPSE2 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs770888946, COSV100984688; called by muse, mutect2, varscan2
- HSF5 | c.1148A>G p.H383R | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as COSV100089719; called by muse, mutect2, varscan2
- HSP90B1 | c.2400del p.D801Mfs*56 | Frame Shift Del (DEL) | VAF 41/224 reads (18%) | catalogued as COSV55354278; called by mutect2, pindel, varscan2
- HSPA12A | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs782338580, COSV100979699; called by muse, mutect2, varscan2
- HSPA1L | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989314; called by muse, mutect2
- HSPG2 | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs781639534, COSV65977032; called by mutect2, varscan2
- HTT | c.1764C>G p.N588K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100750285, COSV100750855; called by muse, mutect2, varscan2
- HTT | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1473464204, COSV61865074; called by muse, mutect2
- HYAL3 | c.697T>C p.W233R | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1553710732; called by muse, mutect2
- ID3 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1421107694; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 18/190 reads (9%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel
- IFI6 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100191388, COSV59269956; called by muse, mutect2, varscan2
- IFT122 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99958595; called by muse, mutect2, varscan2
- IFT140 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101276284; called by muse, mutect2, varscan2
- IFT52 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100887520; called by muse, mutect2
- IGLON5 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99570417; called by muse, mutect2, varscan2
- IL10RB | c.908A>C p.E303A | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV99269731, COSV99270083; called by muse, mutect2, varscan2
- IL17RB | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99860955; called by muse, mutect2, varscan2
- ILDR1 | c.1573A>G p.K525E (on ENST00000344209 / NM_001199799.2; = p.K481E on NM_175924.4) | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs747580467, COSV56551194, COSV99879185; called by muse, mutect2, varscan2
- ILF3 | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs767690509; called by mutect2, varscan2
- IMP4 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759092541, COSV99383579; called by muse, varscan2
- INKA2 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100615727; called by muse, mutect2, varscan2
- IPO9 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV64235321; called by muse, mutect2, varscan2
- IPP | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1348365243; called by muse, mutect2, varscan2
- IQSEC1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56225668; called by muse, mutect2, varscan2
- IRAG1 | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV70211863; called by mutect2, varscan2
- IRF2 | c.150del p.D51Mfs*19 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV101165816; called by mutect2, pindel, varscan2
- IRF4 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV66705115; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.2000G>A p.C667Y | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64535855; called by muse, mutect2
- ISG20L2 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100493904; called by muse, mutect2, varscan2
- ITGA7 | c.1190del p.G397Vfs*7 (on ENST00000555728; = p.G353Vfs*7 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs1361836055; called by mutect2, pindel, varscan2
- ITGA9 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs777429459, COSV99291409; called by mutect2, varscan2
- ITGB1 | c.2132A>G p.N711S | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV56483462; called by muse, mutect2
- IVL | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.608); catalogued as COSV100908081; called by muse, mutect2
- JAG1 | c.1594A>T p.N532Y | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99652335; called by muse, mutect2, varscan2
- JPH1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1482597158, COSV60611522; called by muse, mutect2
- KAT6B | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.124); catalogued as COSV99767166; called by muse, mutect2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 38/312 reads (12%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KBTBD4 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV99772200; called by muse, mutect2, varscan2
- KBTBD7 | c.1775A>G p.E592G | Missense Mutation (SNP) | VAF 32/632 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101067999; called by muse, mutect2
- KCNAB1 | c.701C>T p.A234V (on ENST00000490337 / NM_172160.3; = p.A223V on NM_003471.3) | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs1246455398, COSV56748392; called by muse, mutect2
- KCNC3 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338146006, COSV100979144; called by muse, mutect2, varscan2
- KCNK17 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 94/138 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs191023425, COSV64678206; called by muse, mutect2, varscan2
- KCNN3 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99677124; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDM1B | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs921225400, COSV99923791; called by muse, mutect2, varscan2
- KDM2A | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100445348; called by muse, mutect2, varscan2
- KDM4A | c.429G>A p.K143= | Splice Region (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100969343; called by muse, mutect2, varscan2
- KIAA1109 | c.13075T>A p.S4359T | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV99145436; called by muse, mutect2, varscan2
- KIDINS220 | c.3513T>A p.D1171E | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs776390582, COSV99874763; called by muse, mutect2, varscan2
- KIF1A | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs767331601, COSV57494430; called by muse, mutect2, varscan2
- KIF3A | c.1705A>G p.R569G | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV66415334; called by muse, mutect2, varscan2
- KIF4B | c.2398T>C p.F800L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV70530164; called by muse, mutect2, varscan2
- KIRREL3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746070014, COSV73107063; called by muse, mutect2, varscan2
- KL | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 244/412 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745808758, COSV101198958; called by muse, varscan2
- KLF12 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV66576340, COSV66583201; called by muse, mutect2
- KLF12 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); catalogued as rs1223921454, COSV100888383; called by muse, mutect2
- KLHL1 | c.423del p.L143Wfs*32 | Frame Shift Del (DEL) | VAF 237/549 reads (43%) | catalogued as COSV64784549; called by mutect2, pindel, varscan2
- KLHL42 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV67146013; called by muse, mutect2, varscan2
- KLKB1 | c.1486A>G p.T496A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs144541812; called by mutect2, varscan2
- KLRB1 | c.259+1G>A p.X87_splice | Splice Site (SNP) | VAF 21/282 reads (7%) | catalogued as COSV57590537, COSV99987144; called by muse, mutect2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2C | c.1445T>C p.M482T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs962605833, COSV100065022; called by muse, mutect2
- KMT2D | c.13570C>T p.R4524W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778634045, COSV56457421; called by mutect2, varscan2
- KPRP | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100908651; called by muse, mutect2
- KRI1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as rs777874500, COSV100469627; called by muse, mutect2, varscan2
- KRT1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99358431; called by muse, mutect2
- KRT17 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs368091501, COSV60860308; called by muse, mutect2
- LAMB1 | c.1559A>G p.N520S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV99739625; called by muse, mutect2, varscan2
- LAMB3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as rs1330867759, COSV100620035; called by muse, mutect2, varscan2
- LAMB3 | c.946T>C p.C316R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620037; called by mutect2, varscan2
- LCP1 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59941182; called by muse, mutect2
- LCP2 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV50454182; called by muse, mutect2, varscan2
- LEF1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as rs146861754; called by muse, mutect2, varscan2
- LEFTY2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.879); catalogued as rs1233278598, COSV64746992; called by muse, mutect2
- LETM1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1465591490, COSV100245116; called by muse, varscan2
- LGALS13 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs370450997; called by muse, mutect2, varscan2
- LGALS4 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100313055; called by muse, mutect2
- LIG3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52005519; called by muse, mutect2, varscan2
- LIMA1 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 96/447 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100372158; called by muse, mutect2, varscan2
- LIMK1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs375588485; called by muse, mutect2, varscan2
- LIPC | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100134086; called by mutect2, varscan2
- LIPG | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.167); catalogued as COSV99724226; called by mutect2, varscan2
- LMBRD2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs938938053, COSV99682507; called by muse, mutect2, varscan2
- LNX2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs1251500616, COSV60335580; called by muse, mutect2, varscan2
- LONP2 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754630302, COSV53522904; called by muse, varscan2
- LOXL3 | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV99239384; called by muse, mutect2, varscan2
- LPAR3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); catalogued as rs544005031, COSV101004652; called by mutect2, varscan2
- LRP5 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774342727, CM143633, COSV53713684; called by muse, mutect2, varscan2
- LRP6 | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99742131; called by muse, mutect2, varscan2
- LRRC10 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs373847240; ClinVar: uncertain significance; called by mutect2, varscan2
- LRRC39 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 120/174 reads (69%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV100734299; called by muse, mutect2, varscan2
- LRRC8E | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV60718783; called by muse, mutect2, varscan2
- LRRFIP2 | c.1700-2A>C p.X567_splice | Splice Site (SNP) | VAF 14/186 reads (8%) | catalogued as COSV100368087; called by muse, mutect2
- LRRIQ3 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs534493116, COSV100598687, COSV63044305; called by muse, mutect2, varscan2
- LRTM1 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99835822; called by muse, mutect2, varscan2
- LTK | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs752000156, COSV99540509; called by muse, varscan2
- LUC7L3 | c.1165del p.S389Vfs*3 | Frame Shift Del (DEL) | VAF 57/248 reads (23%) | catalogued as rs1229438198; called by mutect2, pindel, varscan2
- MACF1 | c.21239C>T p.T7080I (on ENST00000372915; = p.T5125I on NM_012090.5) | Missense Mutation (SNP) | VAF 88/119 reads (74%) | catalogued as COSV99240584; called by muse, mutect2, varscan2
- MAEL | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100774749; called by muse, mutect2, varscan2
- MAGEB1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV66775656; called by muse, mutect2, varscan2
- MAP3K12 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs1007891185, COSV57233100; called by muse, mutect2
- MAP3K13 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs765143232, COSV53985938; called by muse, mutect2, varscan2
- MAP3K14 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408097016, COSV100766364, COSV100766571; called by muse, mutect2, varscan2
- MAP4K5 | c.2212A>G p.T738A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs971519838, COSV50162497; called by muse, mutect2, varscan2
- MAP6 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100496375; called by muse, mutect2, varscan2
- MARCHF6 | c.2567T>A p.V856D | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99929262; called by muse, mutect2, varscan2
- MAST4 | c.5637del p.S1880Afs*59 (on ENST00000403625 / NM_001164664.2; = p.S1691Afs*59 on NM_015183.3) | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV99843467, COSV99845332; called by mutect2, varscan2
- MAST4 | c.6108G>T p.W2036C (on ENST00000403625 / NM_001164664.2; = p.W1847C on NM_015183.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV55116785, COSV99842501; called by muse, mutect2, varscan2
- MBD2 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 92/123 reads (75%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs780879642, COSV99839794; called by muse, mutect2, varscan2
- MDGA2 | c.1562C>A p.P521Q (on ENST00000399232 / NM_001113498.2; = p.P223Q on NM_182830.4) | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.166); catalogued as rs866325480, COSV62100215; called by muse, mutect2, varscan2
- ME1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100866287; called by muse, mutect2, varscan2
- MED12 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs759857680, COSV61341687; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MED13L | c.4113C>T p.Y1371= | Splice Region (SNP) | VAF 50/117 reads (43%) | catalogued as rs767543191, COSV99927586; called by muse, mutect2, varscan2
- MED24 | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672901; called by muse, mutect2, varscan2
- MELTF | c.204G>A p.A68= | Splice Region (SNP) | VAF 67/120 reads (56%) | catalogued as rs763657040, COSV99585727; called by muse, varscan2
- METTL23 | c.55_57del p.R19del | In Frame Del (DEL) | VAF 86/121 reads (71%) | catalogued as rs1568010466; called by pindel, varscan2
- MFN2 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99336406; called by muse, mutect2, varscan2
- MGA | c.4399C>T p.R1467C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs769019565, COSV99578151; called by muse, mutect2, varscan2
- MGAT3 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.134); catalogued as COSV100361673; called by muse, mutect2, varscan2
- MITF | c.487C>T p.P163S (on ENST00000448226 / NM_006722.3; = p.P57S on NM_000248.4) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV100096380; called by muse, mutect2
- MKI67 | c.5734G>T p.G1912C | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100896043; called by muse, mutect2
- MKRN1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV55436087; called by muse, mutect2, varscan2
- MMP17 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144538442; called by muse, varscan2
- MMP2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777819097, COSV54600313; called by muse, mutect2, varscan2
- MMP27 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs766084332, COSV52780235; called by muse, mutect2, varscan2
- MMP7 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.957); catalogued as rs751581884, COSV52771701, COSV99497099; called by muse, mutect2, varscan2
- MMRN1 | c.2096A>G p.H699R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as COSV53342503; called by muse, mutect2, varscan2
- MOCS3 | c.1334dup p.L446Pfs*18 | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | catalogued as rs775328079; called by mutect2, pindel, varscan2
- MOGS | c.2422C>A p.Q808K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs995479690; called by muse, mutect2
- MORC2 | c.266A>G p.K89R (on ENST00000397641 / NM_001303256.3; = p.K27R on NM_014941.3) | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53196285, COSV99309352; called by muse, mutect2, varscan2
- MPDZ | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772598863, COSV100056028; called by muse, mutect2, varscan2
- MPRIP | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs944814693, COSV100505198; called by muse, mutect2, varscan2
- MRE11 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1362161636, COSV100119377, COSV60581311; called by muse, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- MRPL1 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV100213701; called by muse, mutect2
- MRPL18 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100364633; called by muse, mutect2
- MRPL18 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV99277083; called by muse, mutect2, varscan2
- MSL2 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100017145; called by mutect2, varscan2
- MTMR3 | c.3131C>T p.T1044I | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100070345; called by muse, mutect2, varscan2
- MTNR1B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as rs754089451, COSV57069050; called by mutect2, varscan2
- MTTP | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.018); catalogued as COSV99644654; called by muse, mutect2, varscan2
- MUC16 | c.10454C>T p.A3485V | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs200594255, COSV101202141, COSV67476944; called by muse, mutect2, varscan2
- MUC4 | c.2213T>G p.L738R | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as COSV100638798; called by muse, mutect2, varscan2
- MYBL2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV99405916; called by muse, mutect2
- MYBPH | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs749355783, COSV55142306; called by muse, mutect2, varscan2
- MYCN | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324334894, COSV99807954; called by muse, mutect2, varscan2
- MYH10 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.358); catalogued as rs77768450; called by muse, mutect2, varscan2
- MYH2 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs369618095; called by muse, mutect2, varscan2
- MYL6B | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs779611293, COSV99255049; called by muse, mutect2, varscan2
- MYL7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs775993597, COSV56269080; called by muse, varscan2
- MYLK | c.472del p.E158Sfs*79 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs770373926; called by mutect2, pindel, varscan2
- MYLK2 | c.1424+1G>A p.X475_splice | Splice Site (SNP) | VAF 33/546 reads (6%) | catalogued as COSV65659902; called by muse, mutect2
- MYO15A | c.5826-1G>T p.X1942_splice | Splice Site (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99230742; called by muse, mutect2
- MYO16 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV51780987; called by muse, mutect2
- MYO1D | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs773457917, COSV59017779; called by mutect2, varscan2
- MYO3B | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100508971, COSV100509905; called by muse, mutect2
- MYO5C | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99953913; called by muse, mutect2, varscan2
- MYO7A | c.5540G>A p.S1847N | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101289011; called by muse, mutect2, varscan2
- NAALAD2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100427937; called by muse, mutect2
- NADK | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364344087; called by muse, mutect2
- NADSYN1 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100034361; called by muse, mutect2, varscan2
- NADSYN1 | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100034365; called by muse, mutect2, varscan2
- NALCN | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99212704; called by muse, mutect2, varscan2
- NAP1L2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs764536615, COSV100999173; called by muse, mutect2, varscan2
- NAPSA | c.997del p.V333Sfs*58 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs568951683; called by mutect2, pindel
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs763376147; called by mutect2, varscan2
- NBPF11 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 60/697 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs1435143148; called by muse, mutect2
- NCAPG2 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs374235532; called by muse, mutect2, varscan2
- NCBP1 | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1429863415, COSV100912512; called by muse, mutect2
- NCDN | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs762381306, COSV61935314; called by muse, mutect2, varscan2
- NDC1 | c.891+2T>C p.X297_splice | Splice Site (SNP) | VAF 21/208 reads (10%) | catalogued as COSV52337442; called by muse, mutect2
- NEB | c.17030T>C p.V5677A | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); catalogued as COSV51430387; called by muse, mutect2
- NEB | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 37/572 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51430410; called by muse, mutect2
- NEDD9 | c.734del p.P245Lfs*3 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as COSV65221569; called by mutect2, pindel, varscan2
- NEK6 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99412627; called by mutect2, varscan2
- NEO1 | c.2877G>T p.K959N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981150; called by muse, varscan2
- NEO1 | c.2934G>T p.Q978H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99981151; called by muse, varscan2
- NEUROD1 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716745; called by muse, mutect2
- NFE2L1 | c.1250T>C p.F417S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100671302; called by muse, mutect2, varscan2
- NFKB1 | c.2507C>T p.A836V (on ENST00000394820 / NM_001382627.1; = p.A837V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373165003; called by mutect2, varscan2
- NFKBIL1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV101092824, COSV65990557; called by muse, mutect2, varscan2
- NIPAL3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs200419498, COSV50231104; called by mutect2, varscan2
- NIPAL3 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99135124; called by muse, mutect2, varscan2
- NISCH | c.2150A>G p.H717R | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.276); catalogued as rs758874650, COSV61901765; called by mutect2, varscan2
- NLRP10 | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149418; called by muse, mutect2, varscan2
- NLRP11 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV100789608; called by muse, mutect2
- NLRP7 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs778545569, CM1210279, COSV60172027; called by muse, mutect2
- NLRP9 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60459687, COSV60463018, COSV60468327; called by muse, mutect2, varscan2
- NOB1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs200973241, COSV99263822; called by muse, mutect2, varscan2
- NOP2 | c.2228A>G p.K743R (on ENST00000322166 / NM_001258308.2; = p.K739R on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/492 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as COSV100350658; called by muse, mutect2
- NPAT | c.3111dup p.K1038Efs*20 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as COSV53717633; called by mutect2, pindel, varscan2
- NPM3 | c.118+2T>C p.X40_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100761637; called by muse, mutect2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as rs774343392; called by mutect2, varscan2
- NRAP | c.2215G>A p.A739T (on ENST00000359988 / NM_001322945.2; = p.A704T on NM_006175.4) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761706634, COSV100748208; called by muse, mutect2, varscan2
- NRAP | c.11A>G p.Q4R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV100748210; called by muse, mutect2, varscan2
- NRK | c.4420C>T p.L1474F | Missense Mutation (SNP) | VAF 169/255 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99686313; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP210L | c.1558A>T p.R520W | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV99667020; called by muse, mutect2, varscan2
- NUP210L | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99666074; called by muse, mutect2
- NUP37 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV99195825; called by muse, mutect2, varscan2
- NWD1 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs568405169, COSV60339667; called by muse, mutect2, varscan2
- NXPH2 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV99739988; called by muse, mutect2, varscan2
- NYNRIN | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1265932641; called by muse, mutect2
- OMD | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs370773585; called by mutect2, varscan2
- OPRD1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs543729900, COSV52379910; called by muse, mutect2, varscan2
- OR10A6 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143603778; called by muse, mutect2, varscan2
- OR2M4 | c.527_528insT p.F177Lfs*4 | Frame Shift Ins (INS) | VAF 90/152 reads (59%) | catalogued as rs774466619, COSV60708759; called by mutect2, pindel*, varscan2
- OR51G2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185474285, COSV58992480; called by muse, mutect2, varscan2
- OR52B4 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs367923959; called by muse, mutect2, varscan2
- OR52M1 | c.98T>G p.F33C | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100798528; called by muse, mutect2
- OR52W1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756662426, COSV60950726; called by muse, varscan2
- OR5B3 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1248575976, COSV100511775, COSV58676817; called by muse, mutect2
- OR5D14 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV100162018; called by muse, mutect2
- OR5D18 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488665846, COSV61736999; called by muse, mutect2, varscan2
- OR5K4 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs908665264, COSV100721283; called by muse, mutect2
- OR5T2 | c.455T>A p.F152Y | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV100506765; called by muse, mutect2, varscan2
- OR7G1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV99528377; called by muse, mutect2, varscan2
- OR7G2 | c.384dup p.A129Cfs*14 | Frame Shift Ins (INS) | VAF 48/116 reads (41%) | catalogued as rs750339447; called by mutect2, varscan2
- OSER1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs373020907; called by muse, mutect2, varscan2
- P2RX3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs775633125, COSV99628264; called by mutect2, varscan2
- P2RY4 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764471136, COSV65736205; called by muse, mutect2, varscan2
- PACC1 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV99800648; called by muse, mutect2, varscan2
- PACRGL | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99763832; called by muse, mutect2
- PAF1 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV99655548; called by muse, mutect2
- PAK2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV59084578; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 20/146 reads (14%) | catalogued as rs751755759; called by mutect2, varscan2
- PAPPA2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs542674982, COSV62777763, COSV62780961; called by muse, mutect2, varscan2
- PARD3B | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202130832, COSV100593218, COSV62535877; called by muse, mutect2, varscan2
- PARVA | c.797A>G p.K266R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV100616381, COSV58513490; called by muse, mutect2, varscan2
- PASK | c.1645T>C p.S549P | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99298475; called by muse, mutect2, varscan2
- PAX6 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs755528147, COSV99569999; called by muse, mutect2, varscan2
- PAXIP1 | c.1626G>C p.Q542H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs915713042, COSV101249709, COSV68185687; called by muse, mutect2, varscan2
- PBLD | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746460984; called by muse, varscan2
- PCDH8 | c.2813A>G p.K938R | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100131097; called by muse, mutect2
- PCDHA1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs782203644, COSV65375202; called by muse, mutect2, varscan2
- PCDHA1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65377231; called by muse, mutect2, varscan2
- PCDHA13 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs201206731, COSV56536176; called by muse, varscan2
- PCDHA2 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs782528536, COSV65367538, COSV65367637; called by muse, mutect2, varscan2
- PCDHB10 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1343147180; called by muse, mutect2
- PCDHB6 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as rs879963699, COSV99169881; called by muse, mutect2, varscan2
- PCDHB8 | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 46/676 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1295047305; called by muse, mutect2
- PCDHGA2 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as COSV53977461; called by mutect2, varscan2
- PCDHGA3 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99528795; called by muse, mutect2
- PCLO | c.6374T>A p.L2125H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV61645993; called by muse, mutect2
- PCSK5 | c.1733A>G p.Q578R | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100949353; called by muse, mutect2, varscan2
- PDCD6 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1244037334, COSV99372509; called by muse, mutect2, varscan2
- PDHA1 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 16/190 reads (8%) | catalogued as COSV63328595; called by muse, mutect2
- PDS5A | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV57824073; called by muse, mutect2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 128/457 reads (28%) | catalogued as rs747131399; called by mutect2, varscan2
- PDSS2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as rs782590458, COSV100942300; called by muse, mutect2, varscan2
- PDZD11 | c.98A>G p.H33R | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV99333455; called by muse, mutect2, varscan2
- PDZD7 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs910111143, COSV64646778; called by muse, mutect2
- PDZRN3 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 54/451 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1378401466, COSV55194414; called by muse, varscan2
- PER3 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100728498; called by muse, mutect2
- PFDN6 | c.260T>G p.I87S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV101004701, COSV65843051; called by muse, mutect2, varscan2
- PHC2 | c.2329C>T p.R777W (on ENST00000257118 / NM_198040.2; = p.R242W on NM_004427.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs199838218, COSV99930615; called by muse, mutect2, varscan2
- PHF23 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs748953713, COSV50035261; called by muse, mutect2, varscan2
- PHTF2 | c.1888C>T p.R630* (on ENST00000248550 / NM_001366089.1; = p.R592* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/195 reads (10%) | catalogued as rs199985778, COSV50331706; called by muse, mutect2, varscan2
- PHYKPL | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs756247782, COSV57424965; called by muse, mutect2, varscan2
- PICALM | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV100707689, COSV62669789; called by muse, mutect2
- PIK3CG | c.955A>T p.R319W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100782436; called by muse, mutect2, varscan2
- PIKFYVE | c.5545C>A p.L1849I | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100009529; called by muse, mutect2, varscan2
- PIP5K1C | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs769334388, COSV100094770; called by muse, varscan2
- PITRM1 | c.2623T>C p.Y875H | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99828145; called by muse, mutect2, varscan2
- PKHD1L1 | c.3218G>A p.S1073N | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV101005125; called by muse, mutect2, varscan2
- PKHD1L1 | c.12637A>T p.T4213S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101005126; called by muse, mutect2
- PKN2 | c.1775A>C p.E592A | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV100281259; called by muse, mutect2, varscan2
- PLA2G15 | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99547029; called by muse, mutect2
- PLAGL1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 222/364 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52788475, COSV99394089; called by muse, mutect2, varscan2
- PLCB4 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV53813228, COSV99593864; called by muse, varscan2
- PLD5 | c.620C>T p.T207M (on ENST00000442594; = p.T145M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs773800524, COSV59134030; called by muse, mutect2, varscan2
- PLEKHM3 | c.1979T>C p.L660S | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66817241; called by muse, mutect2
- PLG | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99804169; called by muse, mutect2, varscan2
- PLOD3 | c.799A>G p.N267D | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777750; called by muse, mutect2, varscan2
- PLTP | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99509591; called by muse, mutect2, varscan2
- PMF1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100195664; called by muse, varscan2
- PMFBP1 | c.268T>A p.L90M | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV99399970; called by muse, mutect2
- PMP22 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1315474014, COSV100396826; called by muse, mutect2, varscan2
- POC1B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs774587323, COSV100544001; called by muse, mutect2, varscan2
- POLDIP3 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1324982005, COSV99348840; called by muse, mutect2, varscan2
- POLE | c.3008A>G p.Y1003C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57683900; called by muse, mutect2, varscan2
- POLN | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 76/202 reads (38%) | catalogued as rs760327169, COSV67025766; called by muse, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 17/94 reads (18%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- POLR1A | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs201827580, COSV99806992; called by mutect2, varscan2
- POLR2A | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59490305; called by muse, mutect2, varscan2
- PPARD | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61099005; called by muse, mutect2, varscan2
- PPFIBP2 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV100205808; called by muse, mutect2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1H | c.1394A>G p.H465R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99955042; called by muse, varscan2
- PPM1N | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99838641; called by muse, mutect2, varscan2
- PPM1N | c.1199G>A p.C400Y | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99838642; called by muse, varscan2
- PPP1R13B | c.802T>A p.L268I | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99157398; called by muse, mutect2, varscan2
- PPRC1 | c.4396C>T p.R1466* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99531241; called by muse, mutect2, varscan2
- PRDM10 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100456523; called by muse, mutect2
- PRDM4 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99946306; called by muse, mutect2
- PREX1 | c.2846G>A p.S949N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as COSV100906007; called by muse, mutect2, varscan2
- PRKCB | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1260666109, COSV57778537; called by muse, mutect2, varscan2
- PRKDC | c.10814dup p.N3605Kfs*3 | Frame Shift Ins (INS) | VAF 32/158 reads (20%) | catalogued as rs1284489077; called by mutect2, varscan2
- PRKDC | c.10532C>T p.A3511V | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV58056707; called by muse, mutect2, varscan2
- PRKDC | c.5870A>G p.N1957S | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV58056717; called by muse, mutect2, varscan2
- PRKDC | c.4226C>T p.S1409F | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs376814572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKG1 | c.808G>T p.G270W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64776371; called by muse, mutect2, varscan2
- PRPSAP1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs756361339, COSV61211505; called by muse, mutect2, varscan2
- PRR5L | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100286765; called by muse, mutect2, varscan2
- PRRC2C | c.6265C>T p.R2089W (on ENST00000367742; = p.R2087W on NM_015172.4) | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776607475, COSV100145080; called by muse, mutect2, varscan2
- PRX | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778936443, COSV99397346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG7 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as COSV101343167; called by muse, mutect2, varscan2
- PSMA2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV55030970, COSV55031353; called by muse, mutect2
- PTCH2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV100941861; called by muse, mutect2, varscan2
- PTCHD1 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV101037140; called by muse, mutect2, varscan2
- PTH1R | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100480740; called by muse, mutect2, varscan2
- PTPN6 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs782599498, COSV100016826, COSV100016895; called by muse, mutect2, varscan2
- PTPRD | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61954919, COSV61957283; called by muse, mutect2, varscan2
- PTPRD | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV61959317; called by muse, mutect2, varscan2
- PTPRF | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV63443726; called by muse, varscan2
- PTPRH | c.2924_2927del p.S975Cfs*77 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | catalogued as rs776785131; called by pindel, varscan2
- PUM1 | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99927371; called by muse, varscan2
- PVR | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs777413448, COSV51822684; called by muse, mutect2, varscan2
- PVR | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51823640; called by muse, mutect2
- PWWP3A | c.1237G>T p.G413* (on ENST00000627377; = p.G412* on NM_032853.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/191 reads (41%) | catalogued as COSV100261669; called by muse, mutect2, varscan2
- PYGB | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99404775; called by muse, mutect2
- PYGB | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV99404776; called by muse, mutect2
- PYGB | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as COSV99404777; called by muse, mutect2, varscan2
- QRICH1 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100676586; called by muse, mutect2
- RAB1B | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100270521; called by muse, mutect2, varscan2
- RAB1B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104394616; called by muse, mutect2, varscan2
- RAB36 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99572058; called by muse, mutect2, varscan2
- RAI14 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs745664992, COSV99461535; called by muse, mutect2, varscan2
- RANBP2 | c.4870A>G p.T1624A | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1351808566; called by muse, mutect2
- RARS2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV101057011; called by muse, mutect2
- RASA3 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs755498753, COSV61868280; called by muse, mutect2
- RASGRF1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs538996118, COSV69179247; called by muse, mutect2
- RASGRF1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101369502; called by muse, mutect2, varscan2
- RASGRP2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs919782236, COSV100818105; called by muse, mutect2, varscan2
- RASSF6 | c.286T>C p.W96R (on ENST00000342081 / NM_201431.2; = p.W64R on NM_177532.5) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100274719; called by mutect2, varscan2
- RB1 | c.2107A>T p.I703F | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV57309651, COSV99922718; called by muse, mutect2, varscan2
992 further variants in this file (559 protein-altering or splice-affecting, 393 silent, 40 other) are not listed here.
